Somatic mutation profile of tumor specimen 0DZOFL from CCDI case PBCTXR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.4 years (5,258 days).
Specimen 0DZOFL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bca3e337-51cc-46cb-9b43-44be50189935.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZOF9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9b6b8f5-646a-418f-ac98-12ee98a79cd5

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.16258G>C p.E5420Q (on ENST00000591111; = p.E4493Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/396 reads (21%) | PolyPhen possibly damaging (0.718); catalogued as rs575592774; called by muse, mutect2, varscan2
- PDE6C | c.2427A>G p.R809= | Silent (SNP) | VAF 94/645 reads (15%) | called by muse, mutect2, varscan2
- WDFY3 | c.9348C>T p.T3116= | Silent (SNP) | VAF 107/362 reads (30%) | catalogued as rs139515171; called by muse, mutect2, varscan2
